Somatic mutation profile of tumor specimen TCGA-AJ-A3NE-01A (aliquot TCGA-AJ-A3NE-01A-11D-A228-09) from TCGA case TCGA-AJ-A3NE, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 46.4 years (16,957 days).
Specimen TCGA-AJ-A3NE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4cfe194b-5f47-4e4b-9928-280e12ed5d4e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AJ-A3NE-10A (Blood Derived Normal), aliquot TCGA-AJ-A3NE-10A-01D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e83f6e5-98c9-4666-be08-8fdc70dd3aa2

The open-access MAF lists 991 somatic variants for this specimen: 723 protein-altering or splice-affecting, 247 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 633, Silent 247, Nonsense Mutation 36, Frame Shift Del 32, Intron 13, Frame Shift Ins 9, Splice Region 6, Splice Site 6, 3'UTR 4, RNA 2, In Frame Del 1, 5'Flank 1.

Variants (750 of 991; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | hotspot (GDC flag); catalogued as rs121913333, CM942020, COSV57320538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APC | c.4495G>T p.G1499* | Nonsense Mutation (SNP) | VAF 7/21 reads (33%) | catalogued as rs756912930, COSV57342655, COSV57345416; ClinVar: likely pathogenic; called by muse, mutect2
- CUL4B | c.923dup p.L308Ffs*5 | Frame Shift Ins (INS) | VAF 16/42 reads (38%) | catalogued as rs1556216330; ClinVar: pathogenic; called by mutect2, varscan2
- F8 | c.3637del p.I1213Ffs*5 | Frame Shift Del (DEL) | VAF 16/55 reads (29%) | catalogued as rs387906450, CD111376, CD930955, CX162002, COSV64271598; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 23/48 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FOXG1 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs796052484, COSV57395928; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GRIN2B | c.1672G>A p.V558I | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as rs1057519004, COSV74206831; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- HNF1A | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs779184183, CM023589, COSV57465633, COSV99982960; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.3261dup p.F1088Lfs*5 | Frame Shift Ins (INS) | VAF 12/28 reads (43%) | hotspot (GDC flag); catalogued as rs267608078; ClinVar: pathogenic; called by mutect2, varscan2
- NF1 | c.2033del p.P678Rfs*10 | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | catalogued as rs587781807, CX1511110; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NF1 | c.4084C>T p.R1362* | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as rs137854560, CM971046, COSV62191433, COSV62213078; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NPC1 | c.1990G>A p.V664M | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs376213990, CM032629; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 11/13 reads (85%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs121913272, COSV55874020; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.401T>C p.M134T | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs1085308046, CM022242, CM1010009, COSV64289820, COSV64299190; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RAG1 | c.1519C>T p.R507W | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs104894298, CM010074; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STXBP2 | c.1430C>T p.P477L | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs121918540, CM096296, COSV99657299; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AACS | c.1942G>A p.V648M | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs765733198, COSV55536128; called by muse, mutect2, varscan2
- ABCA9 | c.1522T>C p.Y508H | Missense Mutation (SNP) | VAF 30/48 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1217178445; called by muse, mutect2, varscan2
- ABCC6 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.224); catalogued as rs776248626, COSV52742326; called by muse, mutect2, varscan2
- AC004922.1 | c.1709C>T p.A570V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.071); catalogued as rs369966813; called by muse, mutect2, varscan2
- ACD | c.889C>T p.R297* (on ENST00000620338; = p.R208* on NM_022914.3) | Nonsense Mutation (SNP) | VAF 3/22 reads (14%) | catalogued as rs1339068886; called by muse, mutect2
- ACO1 | c.664G>A p.G222S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745839445; called by muse, mutect2, varscan2
- ACO2 | c.1270C>T p.R424C | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs767183173; called by muse, mutect2, varscan2
- ADAM22 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs770758181; called by muse, mutect2, varscan2
- ADAMTS16 | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781604712; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2893C>T p.R965C | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as rs780897867, COSV65894384; called by muse, mutect2, varscan2
- ADD3 | c.136C>T p.R46* | Nonsense Mutation (SNP) | VAF 18/48 reads (38%) | catalogued as rs1398020545, COSV53321133; called by muse, mutect2, varscan2
- ADGRF5 | c.3992C>T p.T1331I | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1172588066; called by muse, mutect2, varscan2
- ADGRG4 | c.7265C>T p.A2422V | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs201733840; called by muse, mutect2, varscan2
- ADGRL4 | c.1139T>A p.M380K | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); catalogued as COSV100875485; called by muse, mutect2, varscan2
- ADGRV1 | c.11827C>T p.R3943W | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762677981, COSV67996847; called by muse, mutect2, varscan2
- ADPRS | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs756440961; called by muse, mutect2, varscan2
- AGBL5 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as rs766150855; called by muse, mutect2, varscan2
- AKAP10 | c.1795C>T p.R599* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as rs748488343; called by muse, varscan2
- ALYREF | c.413C>T p.T138M | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); catalogued as rs766803329; called by muse, mutect2, varscan2
- AMIGO3 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV57538677; called by muse, mutect2, varscan2
- ANGPTL4 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as COSV56844537; called by muse, mutect2, varscan2
- ANK1 | c.2803C>T p.R935* | Nonsense Mutation (SNP) | VAF 20/90 reads (22%) | catalogued as COSV99227255; called by muse, mutect2, varscan2
- ANK3 | c.12420del p.K4140Nfs*15 (on ENST00000280772 / NM_001320874.2; = p.K661Nfs*15 on NM_001149.3) | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | catalogued as rs1466658148; called by mutect2, pindel, varscan2
- ANOS1 | c.1516C>T p.R506W | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.634); catalogued as rs201842998, COSV52918569, COSV52928370; called by muse, mutect2, varscan2
- APC | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.194); catalogued as rs748193367, COSV57335627; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOA4 | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.493); catalogued as rs184083285; called by muse, mutect2, varscan2
- APTX | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766690500; ClinVar: uncertain significance; called by muse, mutect2
- ARFGEF2 | c.3644C>T p.A1215V | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.989); catalogued as rs752023536, COSV100904452; called by muse, mutect2, varscan2
- ARHGAP33 | c.368C>T p.P123L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); catalogued as rs556912669; called by muse, mutect2, varscan2
- ARHGAP35 | c.2587C>T p.R863C | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68330957; called by muse, mutect2, varscan2
- ARHGAP6 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs772160289, COSV61626940; called by muse, mutect2
- ARHGEF11 | c.1033T>C p.C345R | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs540397099; called by muse, mutect2, varscan2
- ARHGEF12 | c.2143C>T p.P715S | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV100754670; called by muse, mutect2, varscan2
- ARMC2 | c.1948G>A p.V650M | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1480322734, COSV64551974; called by mutect2, varscan2
- ATAD2 | c.3908A>G p.Q1303R | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.093); catalogued as rs951812541; called by muse, mutect2, varscan2
- ATF6B | c.1579C>T p.R527W | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766245629; called by muse, mutect2, varscan2
- ATF6B | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.205); catalogued as rs376308535, COSV100916813; called by muse, mutect2, varscan2
- ATP2A1 | c.1426C>T p.R476C | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as rs1346843018, COSV63920012, COSV63921615; called by muse, mutect2, varscan2
- ATP6V1D | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.059); catalogued as rs767146743, COSV99370981; called by muse, mutect2, varscan2
- ATXN2L | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs755635449; called by muse, mutect2, varscan2
- B3GNT6 | c.662G>A p.G221D | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV62828372; called by muse, mutect2, varscan2
- B4GALNT1 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756710480, CM136466; called by mutect2, varscan2
- B4GALNT3 | c.2359G>A p.V787M | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.92); PolyPhen benign (0.199); catalogued as rs141658973; called by muse, mutect2, varscan2
- BAG3 | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775645671, COSV64841858, COSV64841948; called by muse, mutect2, varscan2
- BAZ1A | c.844C>T p.R282* | Nonsense Mutation (SNP) | VAF 12/44 reads (27%) | catalogued as rs1200561485; called by muse, mutect2, varscan2
- BEST3 | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368490759; called by muse, varscan2
- BMP1 | c.2506C>T p.R836C | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs202166852, COSV60529648; called by muse, mutect2, varscan2
- BMPR2 | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.104); catalogued as rs570953336, COSV65809762; called by muse, mutect2, varscan2
- BPIFB1 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs149436006, COSV53605013; called by muse, mutect2, varscan2
- BRD2 | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); catalogued as COSV66373847; called by muse, mutect2, varscan2
- BTBD16 | c.965C>T p.P322L | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.75); catalogued as rs563548078, COSV53261615; called by muse, mutect2, varscan2
- BTBD7 | c.173del p.K58Rfs*44 | Frame Shift Del (DEL) | VAF 11/40 reads (28%) | catalogued as rs752512017; called by mutect2, varscan2
- BUB3 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as rs1471446915; called by muse, mutect2, varscan2
- C5 | c.2215C>T p.R739C | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs770615766, COSV56328547; called by muse, mutect2, varscan2
- C5orf15 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as rs1466866543; called by muse, mutect2, varscan2
- CAD | c.2248C>T p.R750* | Nonsense Mutation (SNP) | VAF 9/39 reads (23%) | catalogued as rs1241373335; called by muse, mutect2, varscan2
- CALHM2 | c.946G>A p.V316M | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs1306164523; called by muse, mutect2, varscan2
- CAMSAP1 | c.3386C>T p.T1129M | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.475); catalogued as rs765811813, COSV56724521; called by muse, mutect2, varscan2
- CAPN10 | c.617G>T p.R206M | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.701); catalogued as COSV99550160; called by muse, mutect2, varscan2
- CAPRIN2 | c.1958C>T p.P653L | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs200738608, COSV51831710, COSV99195532; called by muse, mutect2, varscan2
- CARD8 | c.911G>A p.R304Q (on ENST00000651546 / NM_001184900.3; = p.R254Q on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs149533293; called by muse, varscan2
- CCDC117 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs754335519; called by muse, mutect2, varscan2
- CCDC178 | c.874del p.M292Wfs*3 | Frame Shift Del (DEL) | VAF 32/88 reads (36%) | catalogued as rs535192849; called by mutect2, varscan2
- CCN1 | c.19A>G p.R7G | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1352943595; called by muse, mutect2, varscan2
- CCN4 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.458); catalogued as rs760043627, COSV51530809; called by muse, mutect2
- CDC42BPA | c.4862G>A p.R1621H (on ENST00000334218 / NM_001366019.2; = p.R1608H on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs768760090, COSV62021569; called by muse, mutect2, varscan2
- CDC42EP1 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs536131927; called by muse, mutect2, varscan2
- CDH26 | c.2459C>T p.P820L (on ENST00000348616 / NM_177980.4; = p.P153L on NM_021810.6) | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs773831785, COSV99721775, COSV99722858; called by muse, mutect2, varscan2
- CDH3 | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0.072); catalogued as rs763880904; called by muse, mutect2, varscan2
- CDH6 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs773139830, COSV99419265; called by muse, mutect2, varscan2
- CDK20 | c.686C>T p.P229L (on ENST00000325303 / NM_001039803.3; = p.P208L on NM_012119.4) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs545862742; called by muse, mutect2, varscan2
- CDON | c.2764G>A p.E922K | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as rs769676286, CM160061, COSV54997908; called by muse, mutect2, varscan2
- CEP350 | c.8921C>T p.A2974V | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1472246820, COSV62605206; called by muse, mutect2, varscan2
- CEP89 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs758497289, COSV59863689; called by muse, mutect2, varscan2
- CHCHD6 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs756170903; called by muse, varscan2
- CHD4 | c.3490C>T p.R1164C (on ENST00000357008 / NM_001363606.2; = p.R1177C on NM_001273.5) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV58899667; called by muse, mutect2, varscan2
- CIART | c.865G>A p.G289S | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs147269137; called by muse, mutect2, varscan2
- CLIP1 | c.3437T>C p.V1146A (on ENST00000620786 / NM_001247997.1; = p.V1135A on NM_002956.2) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.77); PolyPhen benign (0.014); catalogued as rs1287775791; called by muse, mutect2, varscan2
- CMTM3 | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.146); catalogued as rs777282641; called by muse, mutect2, varscan2
- CNKSR2 | c.1709G>A p.R570H | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1321222847; called by muse, mutect2, varscan2
- COL7A1 | c.3182C>T p.A1061V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as rs553468091; ClinVar: uncertain significance; called by muse, varscan2
- COX10 | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as rs369322304; called by muse, mutect2, varscan2
- CPN1 | c.322C>T p.R108W | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs146812654; called by muse, mutect2, varscan2
- CPZ | c.442C>T p.R148C (on ENST00000360986 / NM_001014447.3; = p.R137C on NM_003652.3) | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs377251041; called by muse, mutect2, varscan2
- CRACD | c.1630G>A p.G544R | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1363465889, COSV51731746; called by muse, mutect2, varscan2
- CREBBP | c.5048G>A p.R1683H | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1247401109, COSV52129686, COSV99268787; called by muse, mutect2, varscan2
- CRLF2 | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs759127718, COSV67493497; called by muse, mutect2, varscan2
- CRMP1 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs373508403, COSV61481822; called by muse, mutect2, varscan2
- CROCC | c.5185C>T p.R1729W | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs763067795; called by muse, mutect2
- CRYBB1 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs369747197; called by muse, mutect2, varscan2
- CSPG4 | c.6277C>T p.R2093C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs765750169; called by muse, mutect2, varscan2
- CSPG4 | c.2591G>A p.R864H | Missense Mutation (SNP) | VAF 77/204 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); catalogued as rs777240528; called by muse, mutect2, varscan2
- CTDP1 | c.1613G>A p.R538Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as rs1260669909, COSV50003417, COSV99311077; called by muse, mutect2, varscan2
- CTNNBL1 | c.172del p.R58Gfs*25 | Frame Shift Del (DEL) | VAF 17/55 reads (31%) | catalogued as rs761516328; called by mutect2, pindel, varscan2
- CUBN | c.9758C>T p.T3253M | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.95); catalogued as rs142446396; called by muse, mutect2, varscan2
- CYP2B6 | c.850A>G p.S284G | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as COSV57842277; called by muse, mutect2, varscan2
- CYTIP | c.463G>A p.G155R | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs747072083, COSV51635211; called by muse, mutect2, varscan2
- DAPK1 | c.2155C>T p.R719C | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.432); catalogued as rs757064991; called by muse, mutect2, varscan2
- DBT | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs775808731; called by muse, mutect2, varscan2
- DCAF4 | c.793G>A p.V265I | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs752249688, COSV62319046; called by muse, mutect2, varscan2
- DCHS1 | c.9277C>T p.R3093* | Nonsense Mutation (SNP) | VAF 17/42 reads (40%) | catalogued as rs1464759146; called by muse, mutect2, varscan2
- DCST1 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs149583518; called by muse, mutect2, varscan2
- DDX4 | c.1943C>T p.S648L | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as rs1441008911, COSV61755475; called by muse, mutect2, varscan2
- DEF6 | c.145G>A p.V49M | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs768719749, COSV100359452; called by muse, mutect2, varscan2
- DENND3 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.085); catalogued as rs777091716, COSV52802905; called by muse, mutect2, varscan2
- DGCR8 | c.1579C>T p.R527C | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61226112; called by muse, mutect2, varscan2
- DHX34 | c.1975C>T p.R659W | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as rs761742358, COSV60897175; called by mutect2, varscan2
- DIAPH1 | c.2603G>A p.R868H | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs1408895782; called by muse, mutect2, varscan2
- DLG3 | c.840G>A p.A280= | Splice Region (SNP) | VAF 19/44 reads (43%) | catalogued as COSV52086620; called by muse, mutect2, varscan2
- DNAH2 | c.2015G>A p.R672H | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.186); catalogued as rs774605240, COSV104430329; called by muse, mutect2, varscan2
- DNAH3 | c.9353C>T p.A3118V | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as rs148895333; called by muse, mutect2, varscan2
- DOC2A | c.853G>A p.G285S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs757458777, COSV100451141, COSV58750916; called by muse, mutect2, varscan2
- DOCK10 | c.1103C>A p.T368N | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs761731122; called by muse, mutect2, varscan2
- DOCK3 | c.5290C>T p.R1764* | Nonsense Mutation (SNP) | VAF 21/62 reads (34%) | catalogued as COSV56528696; called by muse, mutect2, varscan2
- DOCK8 | c.2410G>A p.V804M | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.406); catalogued as rs150038381; called by muse, mutect2, varscan2
- DOT1L | c.1771G>A p.A591T | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.124); catalogued as rs776577348, COSV101288741; called by muse, mutect2, varscan2
- DPM1 | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs750286694; called by muse, mutect2, varscan2
- EDC3 | c.907C>T p.R303W | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV104408210; called by muse, mutect2, varscan2
- EDN3 | c.588G>A p.K196= | Splice Region (SNP) | VAF 16/51 reads (31%) | catalogued as rs768529772; called by muse, mutect2, varscan2
- EEF2 | c.2070C>T p.G690= | Splice Region (SNP) | VAF 8/25 reads (32%) | catalogued as rs748319866; called by muse, mutect2, varscan2
- EEF2KMT | c.784G>A p.V262I | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as rs780207113; called by muse, varscan2
- EGFR | c.2305G>A p.V769M | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.947); catalogued as rs147149347, COSV51802272, COSV51811749; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EHD3 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs763234044, COSV59031550; called by muse, mutect2, varscan2
- ELF3 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as rs761284995, COSV62840994; called by muse, mutect2, varscan2
- ELFN2 | c.1348G>A p.G450S | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs749986197, COSV68746665; called by muse, varscan2
- ENPP7 | c.1153G>A p.V385I | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.437); catalogued as rs140556423; called by muse, mutect2, varscan2
- EP300 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1386169409, COSV54345353; called by muse, mutect2, varscan2
- EPB41L5 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs777262648, COSV55349776; called by muse, mutect2, varscan2
- EPC1 | c.2290G>A p.A764T | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as COSV53926464; called by muse, mutect2, varscan2
- ERGIC1 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as rs376307473; called by muse, mutect2, varscan2
- ERMAP | c.803C>A p.P268H | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.526); catalogued as COSV100072055; called by muse, mutect2, varscan2
- ESCO2 | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767123113, COSV59414087; called by muse, mutect2, varscan2
- ESRP1 | c.1418G>A p.R473H | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.787); catalogued as rs772941059, COSV100619262; called by muse, mutect2, varscan2
- ESS2 | c.1328C>T p.A443V | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs780144981, COSV52817144; called by muse, mutect2, varscan2
- ETNPPL | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs766768915, COSV56595443; called by muse, mutect2, varscan2
- EVPL | c.2173C>T p.R725* | Nonsense Mutation (SNP) | VAF 9/14 reads (64%) | catalogued as rs780394655; called by muse, varscan2
- EXOC3 | c.1954G>A p.V652M | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as COSV59265699; called by muse, mutect2, varscan2
- FAHD2A | c.200C>T p.T67M | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs752005266, COSV99271883; called by muse, mutect2, varscan2
- FAIM2 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs201425199, COSV57740700; called by muse, mutect2, varscan2
- FAM160B2 | c.433G>A p.G145R | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs747529832, COSV57160650; called by muse, mutect2, varscan2
- FAM219B | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.095); catalogued as rs765652617; called by muse, mutect2, varscan2
- FARP1 | c.929T>C p.V310A | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60339867; called by muse, mutect2, varscan2
- FBH1 | c.445C>T p.R149W (on ENST00000362091 / NM_178150.3; = p.R200W on NM_032807.4) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs755192280, COSV62982722; called by muse, mutect2, varscan2
- FBLN1 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs149434866; called by muse, mutect2, varscan2
- FBN2 | c.8407G>A p.V2803I | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs759451244; called by muse, mutect2, varscan2
- FBN3 | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs1317035484, COSV99561180, COSV99561297; called by muse, mutect2, varscan2
- FBXO36 | c.385A>G p.M129V | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs1441996228; called by muse, mutect2, varscan2
- FBXO41 | c.2218C>T p.R740C | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1379678430; called by muse, mutect2, varscan2
- FGF21 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.393); catalogued as rs375892369; called by muse, mutect2, varscan2
- FOXN4 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752891277; called by muse, mutect2
- FRAS1 | c.7988C>T p.A2663V | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs779574423, COSV53615064; called by muse, mutect2, varscan2
- FRYL | c.6772G>A p.V2258I | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.455); catalogued as rs375746522; called by muse, mutect2, varscan2
- FZD3 | c.1369C>T p.R457C | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as rs770596220; called by muse, mutect2, varscan2
- GABRB2 | c.171T>C p.G57= | Splice Region (SNP) | VAF 7/23 reads (30%) | catalogued as rs1554107757; ClinVar: likely benign; called by muse, mutect2, varscan2
- GALNT13 | c.1405T>C p.Y469H | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1053133467; called by muse, mutect2, varscan2
- GFM1 | c.1885G>A p.A629T | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.721); catalogued as COSV99962808; called by muse, mutect2, varscan2
- GFOD1 | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs747626620, COSV64955137; called by muse, mutect2, varscan2
- GFRA2 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV60779688; called by muse, mutect2, varscan2
- GLDN | c.1255G>A p.A419T | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.62); PolyPhen benign (0.01); catalogued as COSV59090441; called by muse, mutect2, varscan2
- GNAS | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.244); catalogued as rs1569032625; called by muse, mutect2, varscan2
- GNB3 | c.140C>T p.T47M | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.83); catalogued as rs116400596; called by muse, mutect2, varscan2
- GNL3L | c.973G>A p.V325M | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs148611493, COSV60577759; called by muse, mutect2, varscan2
- GRAMD1C | c.1882C>T p.R628* | Nonsense Mutation (SNP) | VAF 16/38 reads (42%) | catalogued as rs551072622; called by muse, mutect2, varscan2
- GREM2 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.913); catalogued as COSV100547238, COSV58958209; called by muse, mutect2, varscan2
- GRIK2 | c.49G>A p.V17I | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV59731300; called by muse, mutect2, varscan2
- GRM3 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV64466818; called by muse, mutect2, varscan2
- GRM7 | c.1478G>A p.R493H | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.379); catalogued as rs767400612, COSV63134452; called by muse, mutect2, varscan2
- GUCY2D | c.1237C>T p.R413W | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as rs531612488, COSV54698041; called by muse, mutect2, varscan2
- HCAR2 | c.788C>T p.T263M | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.109); catalogued as rs201581105; called by mutect2, varscan2
- HEATR9 | c.1598C>T p.T533M | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs143722904; called by muse, mutect2
- HECW1 | c.2173G>A p.A725T | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.439); catalogued as rs1313411241, COSV67831345; called by muse, mutect2, varscan2
- HERC2 | c.6428C>T p.A2143V | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.959); catalogued as rs1394393689, COSV55330275, COSV55353074; called by muse, mutect2, varscan2
- HIC2 | c.481del p.R161Afs*113 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | catalogued as rs745918762; called by mutect2, varscan2
- HIF3A | c.1067C>T p.T356M (on ENST00000377670 / NM_152795.4; = p.T287M on NM_022462.4) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs569551991, COSV52196457; called by muse, mutect2, varscan2
- HIP1R | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747076283, COSV53442408; called by muse, mutect2, varscan2
- HIPK2 | c.325G>A p.G109S | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.83); PolyPhen probably damaging (0.923); catalogued as rs780236493, COSV61232551; called by muse, mutect2, varscan2
- HLA-A | c.19C>T p.R7* | Nonsense Mutation (SNP) | VAF 37/99 reads (37%) | catalogued as COSV65136444, COSV65138215; called by muse, mutect2, varscan2
- HNRNPC | c.35G>A p.R12H | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV60144984; called by muse, mutect2, varscan2
- HSPG2 | c.10001G>A p.R3334H | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs746201509; called by muse, mutect2, varscan2
- HSPG2 | c.7318C>T p.R2440W | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1160285381, COSV65969175; called by muse, mutect2, varscan2
- HSPG2 | c.3472C>T p.R1158C | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs200400126, COSV65972570; called by muse, mutect2, varscan2
- HSPH1 | c.1447C>T p.R483* | Nonsense Mutation (SNP) | VAF 7/41 reads (17%) | catalogued as rs1444395962; called by muse, mutect2, varscan2
- IDS | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM950658, COSV61711118; called by muse, mutect2, varscan2
- IFNL1 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs751758716; called by muse, mutect2, varscan2
- IHH | c.556G>A p.V186M | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as rs1384826965; called by muse, mutect2, varscan2
- IL7R | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as rs767559651; called by muse, mutect2, varscan2
- INHBB | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs144228850; called by muse, mutect2, varscan2
- INTS14 | c.971C>T p.A324V (on ENST00000313182 / NM_001366360.2; = p.A245V on NM_001136043.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs771085186; called by muse, mutect2, varscan2
- INTS3 | c.2335G>A p.V779M | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs765309960; called by muse, mutect2, varscan2
- IQSEC1 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs549147535, COSV56227371; called by muse, varscan2
- IQSEC2 | c.2617C>T p.R873C (on ENST00000642864 / NM_001111125.3; = p.R668C on NM_015075.2) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs782383669, COSV100944980; called by muse, mutect2, varscan2
- ISL2 | c.770A>T p.Q257L | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV51958504; called by muse, mutect2, varscan2
- ISM2 | c.1649G>A p.R550Q | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.196); catalogued as rs750799590; called by muse, mutect2, varscan2
- ITGB1BP2 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752930291, COSV52139866; called by muse, mutect2, varscan2
- ITIH1 | c.409A>G p.R137G | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs762646950, COSV56258511; called by muse, mutect2, varscan2
- KCNC2 | c.1684C>T p.R562C | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.014); catalogued as rs199735865, COSV54374815; called by muse, mutect2, varscan2
- KDM5B | c.2878C>T p.R960W | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs570344084, COSV52514689; called by muse, mutect2, varscan2
- KEAP1 | c.1126G>A p.A376T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.111); catalogued as rs530737192; called by muse, mutect2, varscan2
- KHDRBS1 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs746246308; called by muse, mutect2, varscan2
- KIAA1210 | c.1139C>A p.T380N | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV101274068; called by muse, mutect2, varscan2
- KIAA1755 | c.1768C>T p.R590W | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761879258; called by muse, mutect2, varscan2
- KIF14 | c.4204G>A p.G1402S | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377335626; called by muse, mutect2, varscan2
- KLC1 | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs1298390696; called by muse, mutect2, varscan2
- KLK13 | c.514T>C p.Y172H | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs936444815; called by muse, mutect2, varscan2
- KMT2D | c.16590G>T p.W5530C | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); catalogued as COSV56494330; called by muse, mutect2, varscan2
- KRT3 | c.1753G>A p.G585S | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as rs1299411672; called by muse, mutect2, varscan2
- LAMP5 | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV55714924; called by muse, mutect2, varscan2
- LDLR | c.1837G>A p.V613I | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs148181903, CM055381; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- LGI1 | c.988C>T p.R330* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as rs1027289865; called by muse, mutect2
- LIG1 | c.1861G>A p.E621K | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54389666; called by muse, mutect2, varscan2
- LMNB2 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.366); catalogued as rs772843683, COSV57589634; called by muse, varscan2
- LPAR1 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs140255024; called by muse, mutect2, varscan2
- LRP2 | c.2540G>A p.R847H | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as rs537125368, COSV55570631; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRRC8D | c.1763G>A p.R588Q | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.389); catalogued as rs745373233, COSV61577658; called by muse, mutect2, varscan2
- LTBP2 | c.1904C>T p.A635V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs553308964; called by muse, mutect2, varscan2
- LUC7L2 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.127); catalogued as rs758714651; called by muse, mutect2, varscan2
- LZIC | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.416); catalogued as rs765149898; called by muse, mutect2, varscan2
- LZTR1 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.96); catalogued as rs771188127; called by muse, varscan2
- MADCAM1 | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs565184057; called by muse, mutect2, varscan2
- MAGEA6 | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as rs782245197; called by muse, mutect2, varscan2
- MAGEB6 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs775192724, COSV66872018; called by muse, mutect2, varscan2
- MAN1A1 | c.1636C>T p.P546S | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63786350; called by muse, mutect2
- MAN1B1 | c.1216C>T p.R406W | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs1037141680; called by muse, mutect2, varscan2
- MAP3K1 | c.2270G>A p.R757H | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs553060905, COSV101266267; called by muse, mutect2, varscan2
- MARK2 | c.1604C>T p.S535L (on ENST00000402010 / NM_001039469.2; = p.S501L on NM_017490.4) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs1171451343; called by muse, mutect2, varscan2
- MBD3L1 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as rs761880439, COSV59775939; called by muse, mutect2, varscan2
- MEOX2 | c.818C>T p.S273L | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV56289655; called by muse, mutect2, varscan2
- MEPCE | c.2054G>A p.R685Q | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs762750018, COSV99440302; called by muse, mutect2, varscan2
- MFSD3 | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs191044206; called by muse, mutect2, varscan2
- MIEF2 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as rs931096070; called by muse, mutect2, varscan2
- MLC1 | c.476C>T p.T159M | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.742); catalogued as rs777239986; called by muse, mutect2, varscan2
- MLKL | c.722+1G>A p.X241_splice | Splice Site (SNP) | VAF 23/68 reads (34%) | catalogued as rs144019045; called by muse, mutect2, varscan2
- MLXIPL | c.1952G>A p.R651H | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139543215; called by muse, mutect2, varscan2
- MMP17 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.964); catalogued as rs773095803, COSV62178586; called by muse, mutect2, varscan2
- MOCS1 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761671148; called by muse, mutect2, varscan2
- MON1A | c.1232G>A p.R411H | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs765125214; called by muse, mutect2, varscan2
- MORN1 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs765676322, COSV66002511; called by muse, mutect2, varscan2
- MPND | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs1478962192, COSV53655919; called by muse, mutect2, varscan2
- MRAP2 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs545003385, COSV57633731; called by muse, mutect2, varscan2
- MRGPRF | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs754875925; called by muse, mutect2, varscan2
- MROH7 | c.3463C>T p.R1155C | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs181035157, COSV59867742; called by muse, mutect2, varscan2
- MSL3 | c.1058G>A p.R353H (on ENST00000312196 / NM_078629.4; = p.R187H on NM_006800.4) | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV56491941, COSV56494290; called by muse, mutect2, varscan2
- MTMR11 | c.673G>A p.V225I (on ENST00000439741 / NM_001145862.2; = p.V153I on NM_181873.3) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs782665878; called by muse, mutect2, varscan2
- MTPN | c.139C>T p.Q47* | Nonsense Mutation (SNP) | VAF 16/39 reads (41%) | catalogued as COSV104431220; called by muse, mutect2, varscan2
- MUC2 | c.3497G>A p.R1166Q | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs536186048; called by muse, mutect2, varscan2
- MUC5AC | c.16499C>T p.P5500L | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.96); catalogued as rs752599263, COSV100611298; called by muse, mutect2, varscan2
- MYCL | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs768216635, COSV65693368; called by muse, mutect2, varscan2
- MYH11 | c.5197C>T p.R1733C | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1335030890, COSV55564578; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH14 | c.1439C>T p.A480V | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765142655, COSV51822697; called by muse, mutect2, varscan2
- MYO1F | c.2117G>A p.R706H | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as rs771170131, COSV57797846; called by muse, mutect2
- NAALADL1 | c.1789C>T p.R597C | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs771969002; called by muse, mutect2, varscan2
- NALCN | c.2500G>A p.D834N | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99217722; called by muse, mutect2, varscan2
- NAV2 | c.5378G>A p.R1793H (on ENST00000396087 / NM_001244963.2; = p.R1737H on NM_145117.5) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764843299, COSV60657909; called by muse, varscan2
- NBPF1 | c.1621G>A p.V541I | Missense Mutation (SNP) | VAF 17/189 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.23); catalogued as rs768778196; called by muse, mutect2, varscan2
- NCBP1 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.484); catalogued as rs1564018751; called by muse, mutect2, varscan2
- NCLN | c.696+1G>A p.X232_splice | Splice Site (SNP) | VAF 11/36 reads (31%) | catalogued as rs887172105, COSV55743566; called by muse, mutect2, varscan2
- NDUFB10 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs149920175; called by muse, mutect2, varscan2
- NECTIN3 | c.1295G>A p.R432Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.097); catalogued as rs15611, COSV60551510; called by muse, mutect2, varscan2
- NENF | c.344C>T p.T115M | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs200680061, COSV65341348; called by muse, mutect2, varscan2
- NETO1 | c.994A>G p.T332A | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55008774; called by muse, mutect2, varscan2
- NHS | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as rs767395849, COSV66270884; called by muse, mutect2, varscan2
- NID2 | c.3103del p.R1035Gfs*67 | Frame Shift Del (DEL) | VAF 10/23 reads (43%) | catalogued as COSV53499514; called by mutect2, varscan2
- NKAIN2 | c.353C>T p.T118M | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.927); catalogued as rs748832499, COSV63656578; called by muse, mutect2, varscan2
- NLGN4X | c.1583C>T p.T528M | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52040423; called by muse, mutect2, varscan2
- NME4 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.086); catalogued as rs998087751, COSV99556841; called by muse, mutect2, varscan2
- NOMO2 | c.2173G>A p.G725S | Missense Mutation (SNP) | VAF 35/266 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.089); catalogued as rs780085400; called by muse, mutect2, varscan2
- NPAS3 | c.2542G>A p.A848T (on ENST00000356141 / NM_001164749.2; = p.A816T on NM_022123.3) | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs928988596, COSV104415328, COSV60868545; called by muse, mutect2, varscan2
- NPAS4 | c.619C>A p.P207T | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.503); catalogued as COSV100214768; called by muse, mutect2, varscan2
- NR1H4 | c.530G>A p.G177D (on ENST00000551379 / NM_001206993.2; = p.G167D on NM_005123.4) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1409198059; called by muse, mutect2, varscan2
- NR4A1 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1321725750, COSV99671215; called by muse, mutect2, varscan2
- NRIP1 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.942); catalogued as rs890601224; called by muse, mutect2, varscan2
- NRXN1 | c.1970G>A p.R657Q | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.497); catalogued as rs781319797, COSV58452486; called by muse, mutect2, varscan2
- NYAP1 | c.2233C>T p.R745W | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs752933762; called by muse, mutect2, varscan2
- NYAP2 | c.1001C>A p.P334H | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56016153; called by muse, mutect2, varscan2
- OBSCN | c.22750G>A p.G7584S | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as rs1379341766; called by muse, mutect2, varscan2
- OCIAD1 | c.328del p.G111Efs*28 | Frame Shift Del (DEL) | VAF 12/35 reads (34%) | catalogued as COSV51901916; called by mutect2, pindel, varscan2
- OR2T2 | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs751818528; called by muse, mutect2, varscan2
- OR2T27 | c.370G>A p.V124I | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs373763934, COSV100788345; called by muse, mutect2, varscan2
- OR51E2 | c.149C>T p.T50M | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs760468563, COSV104431048; called by muse, mutect2
- OTOF | c.5504C>T p.A1835V (on ENST00000272371 / NM_194248.3; = p.A1068V on NM_004802.4) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.93); catalogued as rs771845825, COSV55511260; called by muse, mutect2, varscan2
- OXER1 | c.266C>T p.S89L | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as rs149597004; called by muse, mutect2, varscan2
- PABPC1L | c.1067G>A p.R356H | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as rs201834135, COSV53839156; called by muse, mutect2, varscan2
- PABPC3 | c.1561G>A p.A521T | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV55801998; called by muse, mutect2, varscan2
- PAK4 | c.211G>A p.V71M | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs765366293; called by muse, mutect2
- PAPPA2 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs576620013, COSV62772155; called by muse, mutect2, varscan2
- PARPBP | c.1232T>A p.I411N | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs748420856; called by muse, mutect2, varscan2
- PCDH11X | c.3712G>A p.A1238T | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as COSV53464812; called by muse, mutect2, varscan2
- PCDHGA4 | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.999); catalogued as rs777545006; called by muse, mutect2
- PCYOX1L | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs780109318; called by muse, mutect2, varscan2
- PDE1B | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs145391059; called by muse, mutect2, varscan2
- PDGFB | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs779509116; called by muse, mutect2, varscan2
- PEF1 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.928); catalogued as rs763547860; called by muse, mutect2, varscan2
- PI4KA | c.5833G>A p.A1945T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1285248765; called by mutect2, varscan2
- PLCB1 | c.550C>T p.R184* | Nonsense Mutation (SNP) | VAF 20/62 reads (32%) | catalogued as rs770826618, COSV62053153; called by muse, mutect2, varscan2
- PLG | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs763808748, COSV51984236; called by muse, mutect2, varscan2
- PLIN4 | c.2101G>A p.V701I (on ENST00000301286; = p.V716I on NM_001367868.2) | Missense Mutation (SNP) | VAF 30/226 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.113); catalogued as rs527524732; called by muse, mutect2
- PLVAP | c.574G>A p.V192M | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs151286294; called by muse, mutect2, varscan2
- PLXNB2 | c.2749G>A p.G917S | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1377653283; called by muse, mutect2
- PLXNB2 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.077); catalogued as COSV63780344; called by muse, mutect2, varscan2
- PLXNB3 | c.2656C>T p.R886C | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs1453766008; called by muse, mutect2, varscan2
- PMVK | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs149231731; called by muse, mutect2, varscan2
- PNMA5 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs1556924312, COSV62626198; called by muse, mutect2, varscan2
- POLD1 | c.1867C>T p.R623W | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs768773535, COSV101486823; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLL | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 24/83 reads (29%) | catalogued as rs369264701; called by muse, mutect2, varscan2
- PPFIA1 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1380857828, COSV54140586; called by muse, mutect2, varscan2
- PPFIBP2 | c.1790T>C p.M597T | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as rs1372141613; called by muse, mutect2, varscan2
- PPP1R12C | c.1110del p.I373Sfs*51 | Frame Shift Del (DEL) | VAF 15/66 reads (23%) | catalogued as COSV54738562; called by mutect2, pindel, varscan2
- PPP1R8 | c.23G>A p.G8D | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.005); catalogued as COSV52580391; called by muse, mutect2, varscan2
- PPP6R1 | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1283276236; called by muse, mutect2, varscan2
- PRICKLE3 | c.568G>T p.G190* | Nonsense Mutation (SNP) | VAF 17/56 reads (30%) | catalogued as COSV66234837; called by muse, mutect2, varscan2
- PRIMPOL | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs764197991, COSV100153136, COSV59248467; called by muse, mutect2, varscan2
- PRKG2 | c.2029C>T p.R677* | Nonsense Mutation (SNP) | VAF 25/57 reads (44%) | catalogued as rs867510159, COSV52331857; called by muse, mutect2, varscan2
- PRMT8 | c.854C>T p.T285M | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.15); catalogued as rs1272004737, COSV54213052; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1348G>A p.V450I (on ENST00000352766; = p.V371I on NM_181334.5) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.003); catalogued as rs200649519; called by muse, mutect2, varscan2
- PSMB11 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs974037882; called by muse, varscan2
- PSMD12 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as rs753760315, COSV62065086; called by muse, mutect2, varscan2
- PSMD6 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs149961547, COSV55760042; called by muse, mutect2, varscan2
- PSTPIP1 | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.098); catalogued as rs754321842, COSV99143561; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTBP3 | c.1448C>T p.P483L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs371111816; called by muse, mutect2, varscan2
- PTPN13 | c.2435G>A p.R812H | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368764035; called by muse, mutect2, varscan2
- PTPN23 | c.2150C>T p.P717L | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs745783479, COSV99651180; called by muse, mutect2, varscan2
- PTPN5 | c.1261G>A p.G421S | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.061); catalogued as rs536008448; called by muse, mutect2, varscan2
- PTPRH | c.1481G>A p.R494H | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.03); catalogued as rs925265680; called by muse, mutect2, varscan2
- PTPRM | c.3747C>T p.D1249= | Splice Region (SNP) | VAF 11/29 reads (38%) | catalogued as rs552851512, COSV59883677; called by muse, mutect2, varscan2
- PXDN | c.2689G>A p.V897M | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200324757, COSV99414054; called by muse, mutect2, varscan2
- RAB11FIP1 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.329); catalogued as rs774399623, COSV54763289, COSV99769616; called by mutect2, varscan2
- RAD54L2 | c.1634G>A p.R545Q | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as rs759822758; called by muse, mutect2, varscan2
- RALGDS | c.191C>T p.T64M | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.153); catalogued as rs1237405970, COSV64428286; called by muse, mutect2, varscan2
- RASAL3 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs751182066; called by muse, mutect2, varscan2
- RASGRF2 | c.3088G>T p.G1030W | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99428266; called by muse, mutect2, varscan2
- RBM14 | c.1622G>A p.R541H | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs369922357; called by muse, mutect2, varscan2
- RBPJL | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs907710511, COSV59213995; called by muse, mutect2, varscan2
- RBPMS | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); catalogued as rs1449308525, COSV55122870; called by muse, mutect2, varscan2
- RELN | c.148G>A p.G50R | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59036629; called by muse, mutect2, varscan2
- RFC5 | c.663+2T>C p.X221_splice | Splice Site (SNP) | VAF 4/18 reads (22%) | catalogued as COSV57478759; called by muse, mutect2
- RHBDF1 | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.031); catalogued as rs759118513; called by muse, mutect2, varscan2
- RIMBP3 | c.3164G>A p.R1055Q | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as rs369966641; called by muse, mutect2, varscan2
- RIMS2 | c.4453G>A p.G1485R (on ENST00000666250 / NM_001348490.2; = p.G1056R on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267601694, COSV51696438; called by muse, mutect2, varscan2
- RNF26 | c.355G>A p.V119I | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs531905313; called by muse, mutect2, varscan2
- RPAP1 | c.3250G>A p.V1084I | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs1566882907; called by muse, mutect2, varscan2
- RPL4 | c.1106C>T p.A369V | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs557402217; called by muse, mutect2, varscan2
- RPS6KA2 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1183944423; called by muse, mutect2, varscan2
- RTP1 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1418244179; called by muse, mutect2, varscan2
- RUNX3 | c.880G>A p.V294M | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs142450822; called by muse, mutect2, varscan2
- RXRA | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as rs768721235, COSV100709315; called by muse, mutect2
- RYR2 | c.3298C>T p.R1100W | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs1411654663, COSV100773446, COSV63707775; called by mutect2, varscan2
- SAMD4B | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as rs771298382, COSV100080672, COSV58750602; called by muse, mutect2, varscan2
- SAMD9L | c.1886G>T p.R629L | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as rs142436298, COSV100560484; called by muse, mutect2, varscan2
- SBF1 | c.5455C>T p.R1819C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs749374352; called by muse, mutect2, varscan2
- SCN11A | c.4048C>T p.R1350W | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753378397; called by muse, mutect2, varscan2
- SDF4 | c.424G>A p.V142M | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs148002594; called by muse, mutect2, varscan2
- SEC16A | c.2857G>A p.G953R | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.388); catalogued as rs763734645, COSV51542428; called by muse, mutect2, varscan2
- SELENBP1 | c.1379G>A p.R460H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs200206735; called by muse, mutect2, varscan2
- SETX | c.3755del p.G1252Dfs*9 | Frame Shift Del (DEL) | VAF 11/31 reads (35%) | catalogued as rs1275836821; called by mutect2, pindel, varscan2
- SFSWAP | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs750912721; called by muse, mutect2, varscan2
- SH3PXD2B | c.2123G>A p.R708H | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs759399077, COSV61126454; called by muse, mutect2, varscan2
- SHANK2 | c.3446C>T p.T1149M | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.177); catalogued as rs1324144512; called by muse, mutect2, varscan2
- SIRT2 | c.529G>T p.G177W | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50876215; called by muse, mutect2, varscan2
- SLC22A18 | c.1177G>A p.V393I | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.234); catalogued as rs139693015; called by muse, mutect2, varscan2
- SLC2A7 | c.832C>T p.R278W | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs765822995, COSV68901973; called by muse, mutect2, varscan2
- SLC35F3 | c.259G>A p.A87T (on ENST00000366617 / NM_001300845.1; = p.A156T on NM_173508.4) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as COSV64020985; called by muse, mutect2, varscan2
- SLC7A1 | c.154G>A p.V52I | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.999); catalogued as rs775434572, COSV66331036; called by muse, mutect2, varscan2
- SLC7A14 | c.187G>A p.V63I | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as rs755029338, COSV51581859; called by muse, mutect2, varscan2
- SMAP1 | c.515del p.K172Rfs*48 (on ENST00000370455 / NM_001044305.3; = p.K145Rfs*48 on NM_021940.5) | Frame Shift Del (DEL) | VAF 16/37 reads (43%) | catalogued as rs763364024; called by mutect2, varscan2
- SMARCC2 | c.3490G>A p.G1164R | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs776531368, COSV99519523; called by muse, mutect2, varscan2
- SMCHD1 | c.4787G>T p.R1596L | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99863030; called by muse, mutect2, varscan2
- SMPD4 | c.1018G>A p.A340T | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.088); catalogued as rs545177321, COSV100302491; called by muse, mutect2, varscan2
- SMTN | c.1477C>T p.R493W | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs748870006, COSV60778616; called by muse, mutect2, varscan2
- SNF8 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1567789338; called by muse, mutect2, varscan2
- SNTA1 | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.226); catalogued as rs138164106; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SNX31 | c.637G>A p.V213M | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs138819788; called by muse, mutect2, varscan2
- SORL1 | c.5444C>G p.S1815C | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.156); catalogued as COSV52759492; called by muse, mutect2, varscan2
- SOX5 | c.1949G>A p.R650H | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs764993534, COSV58627742; called by muse, mutect2, varscan2
- SPAG17 | c.5482C>T p.P1828S | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100307399; called by muse, mutect2, varscan2
- SPAST | c.1366G>A p.D456N | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1330471269; called by muse, mutect2, varscan2
- SPNS2 | c.541G>A p.V181I | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as rs773101280; called by muse, mutect2, varscan2
- SRGAP3 | c.145C>A p.L49I | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV64541533; called by muse, mutect2, varscan2
- SRPRA | c.1870C>T p.R624C | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59742776; called by muse, mutect2, varscan2
- SRRT | c.1352C>T p.A451V | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as rs888110002; called by muse, mutect2, varscan2
- SS18 | c.280G>A p.G94S | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.3); catalogued as rs371528497, COSV99294325; called by muse, mutect2, varscan2
- SSH3 | c.1787C>T p.A596V | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.346); catalogued as rs751291592; called by muse, mutect2, varscan2
- ST3GAL1 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 18/56 reads (32%) | PolyPhen benign (0.299); catalogued as rs751931334; called by muse, mutect2, varscan2
- STAG3 | c.2609G>A p.R870Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as rs548943507, COSV57930769; called by muse, mutect2, varscan2
- STT3A | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.021); catalogued as rs765580288, COSV67065097; called by muse, mutect2, varscan2
- STT3B | c.505G>A p.V169I | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0.213); catalogued as rs747021223; called by muse, mutect2, varscan2
- SYNM | c.1273G>A p.V425I | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs782022980; called by muse, mutect2, varscan2
- SYNPR | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.098); catalogued as COSV55732469; called by muse, mutect2
- TAF1C | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs925194296; called by muse, mutect2
- TAF5 | c.1955G>A p.R652Q | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs931530179; called by muse, mutect2, varscan2
- TANC1 | c.1442G>T p.G481V | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs769640814; called by muse, mutect2, varscan2
- TAOK2 | c.3376C>T p.R1126C | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.725); catalogued as rs750925824; called by muse, mutect2, varscan2
- TBC1D1 | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as rs759106581, COSV54716888; called by muse, mutect2, varscan2
- TCERG1L | c.751G>A p.V251M | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs761516495, COSV100893827; called by muse, mutect2, varscan2
- TECTA | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs886047837, COSV50690989; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TECTA | c.4358G>A p.R1453H | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.703); catalogued as COSV50701625; called by muse, mutect2, varscan2
- TENM4 | c.2704G>A p.V902M | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.539); catalogued as rs547738962, COSV53631657; called by muse, mutect2, varscan2
- TEPSIN | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as rs781165082, COSV56143633; called by muse, mutect2
- TFEC | c.422del p.K141Rfs*42 | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | catalogued as rs771133493, COSV55406589; called by mutect2, varscan2
- THRA | c.1057G>A p.V353I | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.81); PolyPhen benign (0.005); catalogued as rs766284607, COSV52847465; called by muse, mutect2, varscan2
- THSD1 | c.1318G>A p.G440S | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.27); catalogued as COSV51629319; called by muse, mutect2, varscan2
- TIMD4 | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.092); catalogued as rs756150947, COSV50856387; called by muse, varscan2
- TKFC | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs766866933, COSV57102592; called by muse, mutect2, varscan2
- TMCC2 | c.2059G>A p.V687I | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.13); catalogued as rs1457951780, COSV58002279; called by muse, mutect2, varscan2
- TMEM200B | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.053); catalogued as rs1391246431; called by muse, mutect2
- TMEM88 | c.283G>A p.G95R | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs888442600, COSV54687229; called by muse, mutect2, varscan2
- TMPRSS12 | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1220857484, COSV68256999; called by muse, mutect2, varscan2
- TMPRSS15 | c.735A>C p.K245N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV53035198; called by muse, varscan2
- TNC | c.6274G>A p.V2092M | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747231510, COSV60781724; called by muse, mutect2, varscan2
- TNFRSF21 | c.1376C>G p.A459G | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV57281964; called by muse, mutect2, varscan2
- TRAPPC12 | c.1411C>T p.R471C | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs775273317; called by muse, mutect2, varscan2
- TRIM35 | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs1422821170; called by muse, mutect2, varscan2
- TRIM56 | c.350C>T p.T117M | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs1411521784; called by muse, mutect2, varscan2
- TRPM1 | c.1223C>T p.T408M | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.69); PolyPhen benign (0.1); catalogued as rs377213586; called by muse, mutect2
- TRPM2 | c.1948G>A p.A650T | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as rs571733512; called by muse, mutect2, varscan2
- TRPM3 | c.1106G>A p.R369Q (on ENST00000357533 / NM_001366142.2; = p.R214Q on NM_020952.6) | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.277); catalogued as rs768127060, COSV62471809; called by muse, mutect2, varscan2
- TRPM7 | c.388A>G p.M130V | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs1245805855; called by muse, mutect2, varscan2
- TSHZ3 | c.2224C>T p.P742S | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as rs781600374; called by muse, mutect2, varscan2
- TSPEAR | c.518C>T p.T173M | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as rs587742978, COSV59981732; called by muse, mutect2, varscan2
- UBA2 | c.1493C>T p.T498M | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as rs760888384; called by muse, mutect2, varscan2
- UBIAD1 | c.764C>T p.T255M | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.148); catalogued as rs758141480; called by muse, mutect2, varscan2
- UCK2 | c.664G>A p.V222M | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs768645050, COSV63315328, COSV63316628; called by muse, mutect2, varscan2
- UPP2 | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1014463367; called by muse, mutect2, varscan2
- UROD | c.554C>A p.P185H | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV55802029; called by muse, mutect2, varscan2
- USP35 | c.1962del p.T655Pfs*23 | Frame Shift Del (DEL) | VAF 5/23 reads (22%) | catalogued as rs764735138; called by mutect2, varscan2
- UTP20 | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs752186235; called by muse, mutect2, varscan2
- VANGL1 | c.752C>T p.T251M | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.745); catalogued as rs201630629, CM0911457, COSV59621792; called by muse, mutect2
- VDR | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as rs190607107, COSV57470199; called by muse, mutect2, varscan2
- VPS13A | c.1012G>A p.V338I | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs761528876; called by muse, varscan2
- WDR90 | c.1208G>A p.R403H | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.572); catalogued as rs374428893; called by muse, mutect2, varscan2
- WDR90 | c.4085G>A p.R1362Q | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.649); catalogued as rs1293332070; called by muse, mutect2, varscan2
- WNT3A | c.395C>T p.T132M | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.717); catalogued as rs776863772; called by muse, mutect2, varscan2
- WWC1 | c.2335C>T p.R779C | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.845); catalogued as rs201924297, COSV54650266; called by muse, mutect2, varscan2
- XRRA1 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs568448772, COSV100370149; called by muse, mutect2, varscan2
- YTHDF1 | c.1625G>A p.R542H | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs759033271, COSV64832910; called by muse, mutect2, varscan2
- ZBTB7C | c.994G>A p.G332S | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138978875; called by muse, mutect2, varscan2
- ZC2HC1C | c.587C>T p.T196M | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs201860356; called by muse, mutect2, varscan2
- ZFP64 | c.1418C>T p.T473M | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as rs778105974, COSV53801458; called by muse, mutect2, varscan2
- ZHX3 | c.2494C>T p.R832* | Nonsense Mutation (SNP) | VAF 14/67 reads (21%) | catalogued as rs1320639895, COSV58383599; called by muse, mutect2, varscan2
- ZMYND15 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.014); catalogued as rs1303020954, COSV52643306; called by muse, mutect2, varscan2
- ZNF16 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs200923173, COSV52765427; called by muse, mutect2
- ZNF276 | c.370G>A p.A124T (on ENST00000443381 / NM_001113525.2; = p.A49T on NM_152287.4) | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.433); catalogued as rs1025305441; called by muse, mutect2, varscan2
- ZNF337 | c.1159G>A p.V387M | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.385); catalogued as rs771037581, COSV53320120; called by muse, mutect2, varscan2
- ZNF449 | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as rs868938031, COSV100202915; called by muse, mutect2, varscan2
- ZNF606 | c.1220C>T p.T407M | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs148677927; called by muse, mutect2, varscan2
- ZNF646 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.036); catalogued as rs370922757; called by muse, mutect2, varscan2
- ZNF646 | c.4177C>T p.P1393S | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs1447113340; called by muse, mutect2, varscan2
- ZNF71 | c.733G>A p.G245R | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.898); catalogued as COSV60148935; called by muse, mutect2, varscan2
- ZNF74 | c.1570G>A p.G524S | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs926455279; called by muse, mutect2, varscan2
- ZSCAN5B | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs200185124, COSV61999211; called by muse, mutect2, varscan2
- ABCA9 | c.4783C>A p.L1595M | Missense Mutation (SNP) | VAF 33/49 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- ABCF2 | c.1736T>C p.V579A | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- AC004997.1 | c.753G>A p.E251= | Splice Region (SNP) | VAF 6/26 reads (23%) | called by mutect2, varscan2
- ACKR3 | c.823G>T p.D275Y | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACTN3 | c.1394T>C p.V465A | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ACVR2A | c.617T>C p.V206A | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADAMTS20 | c.138G>T p.E46D | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- AFF3 | c.3494C>A p.T1165N | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AKAP8L | c.1222C>A p.L408I | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- ALG10 | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2
- ALMS1 | c.4112C>A p.T1371N | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- AMIGO3 | c.1348G>A p.V450I | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ANK2 | c.43A>G p.K15E | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- ANK3 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- AP2M1 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.082); called by muse, mutect2
- ARID1A | c.4354dup p.Q1452Pfs*39 | Frame Shift Ins (INS) | VAF 12/30 reads (40%) | called by mutect2, pindel, varscan2
- ARID1A | c.6420del p.F2141Sfs*59 | Frame Shift Del (DEL) | VAF 19/42 reads (45%) | called by mutect2, varscan2
- ARID4A | c.194T>C p.I65T | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.82); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARMC4 | c.2447A>G p.N816S | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ATAD5 | c.5446del p.S1816Vfs*21 | Frame Shift Del (DEL) | VAF 13/34 reads (38%) | called by mutect2, pindel, varscan2
- ATM | c.5675A>C p.E1892A | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- ATP9A | c.1262T>C p.V421A | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); called by muse, varscan2
- B4GALT7 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- BABAM2 | c.431C>T p.T144I | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- BFSP2 | c.745C>T p.H249Y | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BMP4 | c.956A>G p.D319G | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- BORA | c.461A>G p.Q154R (on ENST00000613797; = p.Q79R on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- BRPF1 | c.815A>G p.E272G | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- BRWD3 | c.2141A>T p.N714I | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- C5AR2 | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CASK | c.2402C>A p.S801Y (on ENST00000378163 / NM_001367721.1; = p.S796Y on NM_003688.3) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- CASP8AP2 | c.2435T>A p.L812Q | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- CCL20 | c.146T>C p.F49S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CDC37 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- CDR2 | c.134T>C p.L45S | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CELSR1 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CELSR2 | c.3791G>A p.R1264Q | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- CENPI | c.2212A>G p.S738G | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- CERS6 | c.922C>A p.L308I | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CIITA | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- CNTLN | c.3668del p.K1223Rfs*8 | Frame Shift Del (DEL) | VAF 13/33 reads (39%) | called by mutect2, pindel, varscan2
- COL17A1 | c.2662G>T p.G888C | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COPG1 | c.746G>T p.S249I | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.679); called by mutect2, varscan2
- COQ8B | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CPB1 | c.892A>G p.K298E | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- CSDC2 | c.86G>T p.R29M | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- CSMD3 | c.5719G>T p.G1907* (on ENST00000297405 / NM_001363185.1; = p.G1803* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 15/37 reads (41%) | called by muse, mutect2, varscan2
- CTCF | c.610del p.T204Qfs*18 | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | called by mutect2, varscan2
- CYLC1 | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- DAAM2 | c.1694C>T p.P565L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- DCC | c.2904G>T p.Q968H | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- DCP1A | c.1187A>T p.Q396L | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- DDAH1 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- DDAH1 | c.540G>T p.M180I | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- DGKD | c.2177C>T p.A726V (on ENST00000264057 / NM_152879.3; = p.A682V on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- DHH | c.1187G>A p.G396D | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- DHX29 | c.560G>T p.R187M | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DICER1 | c.4049del p.K1350Rfs*29 | Frame Shift Del (DEL) | VAF 18/57 reads (32%) | called by mutect2, pindel, varscan2
- DIP2A | c.1066G>A p.D356N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.607); called by mutect2, varscan2
- DMD | c.6329A>G p.H2110R | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- DMXL2 | c.2489C>T p.P830L | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH2 | c.10731T>A p.H3577Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH7 | c.10966C>T p.R3656C | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- DOCK6 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- DPPA2 | c.620T>C p.I207T | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- DRD5 | c.923G>T p.C308F | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DST | c.8044del p.S2682Afs*19 | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | called by mutect2, pindel, varscan2
- EBP | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EGFL6 | c.1447A>G p.K483E | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.34); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- ELF5 | c.590A>T p.D197V (on ENST00000312319 / NM_198381.2; = p.D187V on NM_001422.4) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPHA2 | c.1379del p.P460Rfs*33 | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | called by mutect2, pindel, varscan2
- EXOC1 | c.2259del p.E754Kfs*18 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | called by mutect2, varscan2
- FAM126B | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FASN | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FAT1 | c.11856dup p.G3953Wfs*19 | Frame Shift Ins (INS) | VAF 13/42 reads (31%) | called by mutect2, pindel, varscan2
- FBXL4 | c.1636G>A p.V546M | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- FDFT1 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FGD1 | c.2866del p.Q956Rfs*25 | Frame Shift Del (DEL) | VAF 20/59 reads (34%) | called by mutect2, pindel, varscan2
- FLRT1 | c.625C>A p.R209S | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- FTL | c.320T>C p.L107P | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- GCC1 | c.623G>T p.R208M | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- GLIS3 | c.1245+2T>C p.X415_splice | Splice Site (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- GPR108 | c.1133C>T p.A378V (on ENST00000264080 / NM_001080452.1; = p.A136V on NM_020171.2) | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- GPR17 | c.487C>T p.H163Y | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- GPX2 | c.43A>C p.S15R | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- GRIP2 | c.2419A>C p.S807R (on ENST00000619221; = p.S710R on NM_001080423.4) | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GTSF1 | c.50G>A p.C17Y | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HAS3 | c.127C>A p.L43M | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.878); called by muse, mutect2
- HDLBP | c.2240del p.G747Afs*27 | Frame Shift Del (DEL) | VAF 5/33 reads (15%) | called by mutect2, pindel
- HLA-B | c.82T>C p.S28P | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- IBA57 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IFT172 | c.4624G>A p.A1542T | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.198G>A p.W66* | Nonsense Mutation (SNP) | VAF 28/97 reads (29%) | called by muse, varscan2
- IGSF22 | c.2032A>G p.I678V | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.73); PolyPhen benign (0.001); called by muse, mutect2
- IKZF4 | c.233C>A p.P78H | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); called by mutect2, varscan2
- IL1R2 | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- KCNH1 | c.2260G>A p.A754T (on ENST00000271751 / NM_172362.3; = p.A727T on NM_002238.4) | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCNH3 | c.2683A>T p.M895L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- KHDRBS1 | c.871C>T p.R291W | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- KIAA0408 | c.925T>C p.Y309H | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIRREL1 | c.1031del p.K344Rfs*7 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | called by mutect2, pindel, varscan2
- KLHL28 | c.155T>C p.V52A | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- KMT2B | c.2215C>T p.Q739* | Nonsense Mutation (SNP) | VAF 28/83 reads (34%) | called by muse, mutect2, varscan2
- KRT5 | c.202C>A p.L68M | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- LHX6 | c.128C>A p.S43Y (on ENST00000373755 / NM_001242334.2; = p.S72Y on NM_014368.5) | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- LILRA4 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.597); called by muse, varscan2
- LNPEP | c.690dup p.Q231Tfs*3 | Frame Shift Ins (INS) | VAF 9/47 reads (19%) | called by mutect2, pindel, varscan2
- LNPEP | c.2458C>T p.R820W | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LOXL2 | c.2021C>T p.A674V | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- LRP8 | c.1052G>A p.C351Y | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRTOMT | c.398C>T p.T133I | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LSM14B | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- LTBP4 | c.4746G>T p.E1582D (on ENST00000308370 / NM_001042544.1; = p.E1545D on NM_003573.2) | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- LY75 | c.4683del p.K1561Nfs*15 | Frame Shift Del (DEL) | VAF 15/58 reads (26%) | called by mutect2, pindel, varscan2
- LYVE1 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAOA | c.1571T>C p.L524P | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- MAP3K21 | c.1653G>A p.M551I | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP7D1 | c.107del p.P36Hfs*20 | Frame Shift Del (DEL) | VAF 9/23 reads (39%) | called by mutect2, pindel, varscan2
- MDN1 | c.15773G>T p.R5258L | Missense Mutation (SNP) | VAF 56/153 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- MED13 | c.5382C>A p.Y1794* | Nonsense Mutation (SNP) | VAF 8/19 reads (42%) | called by muse, mutect2, varscan2
- MED13L | c.1438C>T p.Q480* | Nonsense Mutation (SNP) | VAF 14/63 reads (22%) | called by muse, mutect2, varscan2
- MED20 | c.19T>C p.S7P | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- METTL16 | c.564del p.F188Lfs*10 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | called by mutect2, pindel
- MFHAS1 | c.538C>A p.L180I | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- MID1 | c.1508A>G p.N503S | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- MLLT6 | c.2993C>T p.A998V | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- MROH2B | c.2426C>T p.A809V | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MTR | c.1259G>A p.G420D | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- MTX2 | c.92A>T p.E31V | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- MXRA7 | c.387A>T p.E129D | Missense Mutation (SNP) | VAF 15/67 reads (22%) | PolyPhen benign (0.042); called by muse, mutect2, varscan2
- MZF1 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- NAB2 | c.1144-2A>G p.X382_splice | Splice Site (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2, varscan2
- NADK2 | c.860G>T p.R287M (on ENST00000381937 / NM_001085411.3; = p.R124M on NM_153013.4) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NAV2 | c.4076G>A p.G1359D (on ENST00000396087 / NM_001244963.2; = p.G1336D on NM_145117.5) | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- NEK10 | c.3325T>C p.S1109P | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NHLRC2 | c.1456del p.R486Gfs*27 | Frame Shift Del (DEL) | VAF 16/65 reads (25%) | called by mutect2, pindel, varscan2
- NISCH | c.3791T>C p.L1264P | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- NKRF | c.321A>G p.I107M | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NOS1AP | c.1474C>T p.Q492* | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2
- NPAS4 | c.431-1G>A p.X144_splice | Splice Site (SNP) | VAF 23/104 reads (22%) | called by muse, varscan2
- NR4A2 | c.1670G>A p.G557E | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- NRP2 | c.1327G>T p.G443C | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRROS | c.927C>A p.N309K | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- NUP210 | c.4435T>C p.S1479P | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.26); called by mutect2, varscan2
- NUP214 | c.3051dup p.V1018Rfs*20 | Frame Shift Ins (INS) | VAF 13/40 reads (33%) | called by mutect2, pindel, varscan2
- OR6C65 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.107); called by muse, mutect2
- OR8H1 | c.625T>C p.S209P | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- PANK2 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PANK4 | c.1087G>A p.G363R | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHA4 | c.230T>A p.V77E | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- PCDHB2 | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- PDE9A | c.1602G>A p.M534I | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDP2 | c.1286G>T p.G429V | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- PDPN | c.206C>T p.A69V (on ENST00000621990; = p.A145V on NM_006474.4) | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- PEA15 | c.74C>T p.S25L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- PEX16 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2
- PHACTR2 | c.64G>T p.G22C | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PHC1 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.068); called by muse, mutect2
- PHRF1 | c.2783T>C p.L928P (on ENST00000264555 / NM_001286581.2; = p.L927P on NM_020901.4) | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- PICK1 | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PIF1 | c.1012C>T p.L338F | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLCH2 | c.3253C>A p.L1085M | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- PLEC | c.1225del p.V409* (on ENST00000322810 / NM_201380.4; = p.V299* on NM_000445.5) | Frame Shift Del (DEL) | VAF 15/51 reads (29%) | called by mutect2, pindel, varscan2
- PLXNA1 | c.1895A>G p.Q632R | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLXNA2 | c.2698C>T p.P900S | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.05); called by muse, mutect2
- PLXNA4 | c.1371G>T p.K457N | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- POLR1B | c.1688T>A p.V563D | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- PRAG1 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- PSPC1 | c.1010T>G p.L337R | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTCD1 | c.1660A>G p.N554D | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- PTEN | c.170dup p.L57Ffs*6 | Frame Shift Ins (INS) | VAF 18/45 reads (40%) | called by mutect2, pindel, varscan2
- PTPRE | c.1132G>A p.V378I | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- RABGAP1 | c.2611C>T p.R871W | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- RAI1 | c.3976G>T p.G1326C | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RALGAPA1 | c.440A>G p.Q147R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- REV1 | c.1393C>A p.L465M | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RHBDL3 | c.1091G>T p.R364M | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- RHPN2 | c.1921C>A p.L641M | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNASET2 | c.683T>A p.L228Q | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- RNF123 | c.2335T>C p.Y779H | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RNGTT | c.1648T>C p.S550P | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- ROBO1 | c.3955G>C p.V1319L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- RPH3A | c.1779G>A p.W593* (on ENST00000389385 / NM_001143854.2; = p.W589* on NM_014954.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | called by muse, mutect2, varscan2
- RPL6 | c.78G>T p.K26N | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- RPS2 | c.655A>T p.I219F | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- RTCA | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RUFY1 | c.1503G>T p.M501I | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- SALL3 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- SAMD4A | c.1720G>T p.G574C | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- SATB1 | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCN1A | c.1931C>G p.T644S | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- SDAD1 | c.1090C>A p.L364I | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- SDK1 | c.4604C>T p.A1535V | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SEC24A | c.118C>A p.L40M | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEMA3F | c.65C>T p.T22I | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, varscan2
- SEMA7A | c.431G>A p.G144D | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SESN1 | c.859C>T p.R287* (on ENST00000356644 / NM_001199933.1; = p.R346* on NM_014454.3) | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- SESN2 | c.167A>G p.E56G | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SETD1A | c.1406G>C p.G469A | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SFTPC | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SH3PXD2A | c.1812G>T p.K604N (on ENST00000369774 / NM_001365079.1; = p.K576N on NM_014631.2) | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- SH3RF3 | c.719A>G p.Q240R | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SHANK2 | c.4027A>C p.S1343R | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- SIGLEC11 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- SKOR1 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC12A5 | c.781C>T p.L261F (on ENST00000454036 / NM_001134771.2; = p.L238F on NM_020708.5) | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SLC1A3 | c.1445C>T p.T482I | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.76); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- SLC27A3 | c.1396G>A p.G466S (on ENST00000271857; = p.G338S on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- SLC32A1 | c.622G>A p.V208I | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- SLITRK1 | c.638C>A p.P213H | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- SLX4 | c.4049del p.G1350Afs*25 | Frame Shift Del (DEL) | VAF 15/50 reads (30%) | called by mutect2, pindel, varscan2
- SMARCA4 | c.1472G>T p.R491I | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- SNRK | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SORL1 | c.197C>A p.A66D | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, mutect2
- SOS1 | c.1479G>T p.K493N | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SPTA1 | c.5615A>G p.E1872G | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SPTAN1 | c.3098A>G p.E1033G | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- SRGAP1 | c.482T>G p.L161R | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STRN4 | c.1334C>A p.A445D | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- STX1B | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by mutect2, varscan2
- SUGP1 | c.1558C>T p.R520W | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- SVIL | c.4959A>C p.K1653N (on ENST00000355867 / NM_021738.3; = p.K1227N on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- SYNE2 | c.2843A>G p.K948R | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.031); called by muse, mutect2
- TBX22 | c.449A>G p.K150R | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- TDRD1 | c.1567C>T p.L523F | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TEP1 | c.7740G>A p.W2580* | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- TEX30 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TICRR | c.4396C>A p.L1466I | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- TMEM17 | c.563T>C p.M188T | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMEM176A | c.214G>T p.G72* | Nonsense Mutation (SNP) | VAF 16/58 reads (28%) | called by muse, mutect2, varscan2
- TMEM200C | c.311G>A p.S104N | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TMEM219 | c.451C>A p.L151I | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TNFAIP8 | c.503del p.L168Wfs*36 | Frame Shift Del (DEL) | VAF 32/97 reads (33%) | called by mutect2, pindel, varscan2
- TP73 | c.451C>A p.L151I | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); called by muse, mutect2
- TRAF2 | c.1253A>G p.N418S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRIP12 | c.2384C>T p.A795V | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- TTBK1 | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TTC21B | c.2065G>T p.E689* | Nonsense Mutation (SNP) | VAF 16/55 reads (29%) | called by muse, mutect2, varscan2
- TTN | c.100573G>T p.G33525* (on ENST00000591111; = p.G26101* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | called by muse, mutect2, varscan2
- TTN | c.22214A>G p.Q7405R (on ENST00000591111; = p.Q6478R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | PolyPhen benign (0.229); called by muse, mutect2
- UAP1 | c.1319T>C p.F440S | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- UBA1 | c.1630C>T p.R544W | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- UBA2 | c.203T>C p.V68A | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- UBXN6 | c.836C>A p.P279H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- USF3 | c.5351dup p.P1785Tfs*3 | Frame Shift Ins (INS) | VAF 12/45 reads (27%) | called by mutect2, pindel, varscan2
- USP11 | c.965C>T p.S322L (on ENST00000218348; = p.S279L on NM_001371072.1) | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USP9X | c.4086+1dup | Frame Shift Ins (INS) | VAF 18/58 reads (31%) | called by mutect2, pindel, varscan2
- UTP20 | c.5928G>T p.Q1976H | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- VCAN | c.7444T>C p.F2482L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- WASF1 | c.437_439del p.E146del | In Frame Del (DEL) | VAF 8/44 reads (18%) | called by pindel, varscan2
- WASHC5 | c.3272A>G p.Y1091C | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- WBP1L | c.253C>T p.R85* | Nonsense Mutation (SNP) | VAF 15/60 reads (25%) | called by muse, mutect2, varscan2
- WTAP | c.496C>T p.Q166* | Nonsense Mutation (SNP) | VAF 16/52 reads (31%) | called by muse, mutect2, varscan2
- YIPF7 | c.550C>A p.L184I | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ZNF320 | c.897A>C p.K299N | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZNF343 | c.1763A>G p.H588R | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF346 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- ZNF586 | c.209G>T p.S70I | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.093); called by muse, mutect2
- A1CF | c.598C>T p.L200= | Silent (SNP) | VAF 15/49 reads (31%) | called by muse, mutect2, varscan2
- ABCC4 | c.1314C>T p.G438= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs150945397; called by muse, mutect2, varscan2
- ABCD1 | c.561C>T p.D187= | Silent (SNP) | VAF 38/99 reads (38%) | catalogued as rs781987852; called by muse, mutect2, varscan2
- ABCD1 | c.2163C>A p.G721= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV54384783; called by muse, mutect2, varscan2
- ACAT1 | c.1230C>A p.A410= | Silent (SNP) | VAF 20/60 reads (33%) | called by muse, mutect2, varscan2
- ACP6 | c.765C>T p.N255= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs782702420, COSV100984178; called by muse, mutect2, varscan2
- ADAM22 | c.1068C>T p.G356= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as rs770231524, COSV55974590; called by muse, mutect2, varscan2
- ADAMTS13 | c.2022C>A p.T674= | Silent (SNP) | VAF 14/50 reads (28%) | called by muse, mutect2, varscan2
- ADGRV1 | c.15009C>T p.G5003= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs375195936, COSV67979770; called by muse, mutect2, varscan2
- AKNA | c.2364G>A p.E788= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV99800758; called by muse, mutect2, varscan2
- AKTIP | c.279C>T p.G93= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs989640238; called by muse, mutect2, varscan2
- AMMECR1L | c.291C>T p.N97= | Silent (SNP) | VAF 18/56 reads (32%) | called by muse, mutect2, varscan2
- ANK1 | c.1503C>T p.T501= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as rs145793923; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APLNR | c.612G>A p.S204= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs767808263, COSV57242043; called by muse, mutect2, varscan2
- ARAF | c.639G>A p.T213= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as rs144376609; called by muse, mutect2, varscan2
- ARHGEF40 | c.3765C>T p.A1255= | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as rs148116920; called by muse, mutect2, varscan2
- ARRDC2 | c.1209C>T p.R403= | Silent (SNP) | VAF 19/39 reads (49%) | called by muse, mutect2
- ARSI | c.180C>T p.H60= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs1050927481, COSV100156078; called by muse, mutect2, varscan2
- ATAD3A | c.1057C>A p.R353= | Silent (SNP) | VAF 29/115 reads (25%) | catalogued as rs770892654; called by muse, mutect2, varscan2
- ATAT1 | c.1149C>T p.H383= (on ENST00000376485; = p.H371= on NM_001031722.4) | Silent (SNP) | VAF 7/18 reads (39%) | called by muse, mutect2, varscan2
- ATP1A2 | c.204C>T p.D68= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as rs745431386, COSV100767829; called by muse, mutect2, varscan2
- ATRNL1 | c.1359T>C p.T453= | Silent (SNP) | VAF 9/41 reads (22%) | called by muse, mutect2, varscan2
- BRAF | c.2307A>G p.S769= (on ENST00000288602 / NM_001374244.1; = p.S729= on NM_004333.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2, varscan2
- BRAP | c.354G>A p.P118= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as rs375357747; called by muse, mutect2, varscan2
- BRD9 | c.1167G>A p.A389= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as rs150581830; called by muse, mutect2, varscan2
- BRSK1 | c.2046C>T p.S682= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as rs372118776; called by muse, mutect2, varscan2
- CACNA1H | c.6261C>T p.G2087= | Silent (SNP) | VAF 13/22 reads (59%) | catalogued as rs372118811; called by muse, mutect2, varscan2
241 further variants in this file (0 protein-altering or splice-affecting, 220 silent, 21 other) are not listed here.
